Somatic mutation profile of tumor specimen BLGSP-71-19-00106-02A (aliquot BLGSP-71-19-00106-02A-01D-A634-33) from CGCI case BLGSP-71-19-00106, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.2 years (3,003 days).
Specimen BLGSP-71-19-00106-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Testis; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1e5899-04c8-4680-89fa-53ee3f6afc1f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00106-10A (Blood Derived Normal), aliquot BLGSP-71-19-00106-10A-01D-A634-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ece37146-6181-4634-8a6d-e94e44d5b124

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, varscan2
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 35/75 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 68/230 reads (30%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.712T>C p.C238R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519981, CM025271, CM056070, COSV52699956, COSV52707471, COSV52711035, COSV52711932; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYC | c.743C>T p.T248I (on ENST00000377970; = p.T263I on NM_002467.6) | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1020542388; called by muse, mutect2, varscan2
- PCBP1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as rs797044899, COSV57851598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRYL | c.5645C>A p.A1882D | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GNAI2 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- P2RY8 | c.704_705del p.A235Gfs*107 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by pindel, varscan2
- MYC | c.174C>T p.T58= (on ENST00000377970; = p.T73= on NM_002467.6) | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs1212274221, COSV52368991; called by muse, varscan2
